Gene-level copy-number profile of tumor specimen TCGA-44-6147-01B from TCGA case TCGA-44-6147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-44-6147-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.57e73b3a-1042-4924-bcbd-0c5eba914bec.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6147-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/a460b3dc-2d24-4e02-87b9-e2f39fb4c49d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 562; copy number 2: 59,593; copy number 3: 75; copy number 4: 28; copy number 5: 5; copy number 6: 6; copy number 7: 1; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-44-6147-01): tumor purity 0.47, ploidy 1.93, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:19,435,063–19,435,158, 1 gene: MIR640.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:52,297,995–52,298,096, 1 gene, copy number 7: Y_RNA.
- chr2:76,684,975–76,698,996, 2 genes, copy number 6 (within-gene range 1–6): AC068616.3, AC068616.1.
- chr7:6,329,411–6,365,770, 3 genes, copy number 5: FAM220A, AC009412.1, RPSAP73.
- chr7:62,275,361–62,275,678, 1 gene, copy number 9: AC128676.1.
- chr8:96,222,947–96,261,610, 3 genes, copy number 6: UQCRB, AP003465.1, MTERF3.
- chr20:36,996,349–37,095,997, 1 gene, copy number 5 (within-gene range 2–5): RBL1.
- chr20:37,049,254–37,049,707, 1 gene, copy number 5: RPS27AP3.

Autosomal genes at a single copy (total copy number 1): 40. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
